Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4975, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4975-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4975

Clinical Diagnosis & History:

with incidentally diagnosed right renal mass.

Specimens Submitted:

1: SP: Kidney, right posterior mid pole, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right posterior mid pole, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 5.0 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh for intraoperative consultation and is labeled "right posterior mid-pole kidney mass; stitch marks deep margin". It consists of a 10.2 x 6.5 x 4.5 cm wedge-shaped portion of kidney with a suture marking the deep margin and attached fibroadipose tissue measuring 10 x 8.5 x 2.0 cm. Detached fragments of fibroadipose tissue are also identified measuring 21 x 7.0 x 3.0 cm. The margin is inked black and the specimen is serially sectioned to reveal a well defined, hemorrhagic variegated yellow mass measuring 5.0 x 3.9 x 3.5 cm. The clearance from the resection margin is 0.1 cm. The mass appears to abut the perirenal fat, but is far away from Gerota's fascia. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T c- tumor with renal capsule

M - margin

k-normal kidney

f - perirenal fat

adm-additional sections of margin

Summary of Sections:

Part 1: SP: Kidney, right posterior mid pole, partial nephrectomy

Block	Sect. Site	PCs
3	adm	3
2	f	2
1	fsc	1
1	k	1
2	m	2
3	tc	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA. MARGIN NOT INVOLVED.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file b44bf6ac-644c-4604-b5fc-2b6633d56990 (TCGA-BP-4975.E2FF0050-6701-4191-955F-1419B74C95B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).